TARGET case TARGET-10-PAPHRT — Acute Lymphoblastic Leukemia - Phase II (TARGET-ALL-P2)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Lymphoid Leukemias; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/8d1e0bbd-8af3-54ac-99c4-39f5ebf828e1

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Age at index: 18 years; Vital status: Alive.

Diagnoses (1)
1. Acute lymphocytic leukemia: ICD-O-3 morphology code: 9835/3; ICD-10 code: C91.0; Tissue or organ of origin: Bone marrow; Classification of tumor: primary; Age at diagnosis: 18.2 years (6,631 days); Year of diagnosis: 2006; Days to last follow up: 2,150 days (5.9 years).
   Treatment given: Protocol identifier: AALL0232.

Follow-up (2 entries)
- Days to follow up: 28 days; Days to first event: 28 days; First event: Induction Failure.
- Days to follow up: 2,150 days (5.9 years); Year of follow up: 2012.

Molecular and laboratory tests (laboratory values grouped by visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- BCR–ABL1 fusion: Negative.
- Day 0: Leukocytes 45.6 ×10³/µL.
- Day 8: Bone Marrow blast count 88%.
- Day 15: Bone Marrow blast count 55%.
- Day 29: Bone Marrow blast count 72%; Minimal Residual Disease (Flow Cytometry) 32.8%.

Biospecimens (3 samples)
- Sample TARGET-10-PAPHRT-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
- Sample TARGET-10-PAPHRT-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.
- Sample TARGET-10-PAPHRT-14A: Sample type: Bone Marrow Normal; Tissue type: Normal; Specimen type: Bone Marrow NOS.

Additional fields from the TARGET clinical supplement workbook TARGET_ALL_ClinicalData_Phase_II_Discovery_20230727.xlsx:
- Overall Survival Time in Days: 2150
- WBC at Diagnosis: 45.58
- CNS Status at Diagnosis: CNS 1
- Testicular Involvement: No
- MRD Day 29: 32.8
- MRD Day 29 Sensitivity: 0.01
- Bone Marrow Site of Relapse: No
- CNS Site of Relapse: No
- Testes Site of Relapse: No
- Other Site of Relapse: No
- BCR ABL1 Status: Negative
- BMA Blasts Day 8: 88
- BMA Blasts Day 15: 55
- BMA Blasts Day 29: 72
- Down Syndrome: No
- DNA Index: 1
- Cell of Origin: B-Precursor
- ALL Molecular Subtype: None of the above
